Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A1NX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A1NX-01A (Primary Tumor).

[page 1 of 4]
105-0-3

adenocarcinoma, serous, NOS 8441/3

Site: Endometrium C54.1

2/24/11 JW

Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

- A. Soft tissue, ileal serosa, biopsy: Benign fibroadipose tissue, negative for tumor.
- B. Soft tissue, anterior vaginal mucosa, biopsy: Benign squamous mucosa and submucosa, negative for tumor.
- C. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade 3 (of 3) endometrial serous adenocarcinoma is identified forming a mass (5.5 x 5.2 x 1.5 cm), circumferentially involving the endometrial cavity and lower uterine segment. The tumor invades 2.0 cm into the myometrium (total wall thickness 2.1 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are not involved.
- D. Lymph nodes, left pelvic, lymphadenectomy: Multiple (7 of 25) left pelvic lymph nodes are positive for metastatic serous adenocarcinoma.
- E. Lymph nodes, right pelvic, lymphadenectomy: Multiple (1 of 14) right pelvic lymph nodes are positive for metastatic serous adenocarcinoma.
- F. Omentum, omentectomy: Negative for neoplasm.

[page 2 of 4]
G. Lymph nodes, left para-aortic above inferior mesenteric artery,
lymphadenectomy: A single (1 of 2) left para-aortic lymph node
above inferior mesenteric artery, is positive for metastatic serous adenocarcinoma.

H. Lymph nodes, left para-aortic below inferior mesenteric artery,
lymphadenectomy: Multiple (4 of 13) left para-aortic lymph nodes
below inferior mesenteric artery, is positive for metastatic serous adenocarcinoma.

I. Gonadal vessel, left, biopsy: Negative for neoplasm.

J. Lymph nodes, right para-aortic above inferior mesenteric artery,
lymphadenectomy: Multiple (6) right para-aortic lymph nodes above
inferior mesenteric artery, are negative for tumor.

K. Lymph nodes, right para-aortic below inferior mesenteric artery,
lymphadenectomy: Multiple (2 of 2) right para-aortic below inferior
mesenteric artery, are positive for metastatic serous adenocarcinoma.

L. Gonadal vessel, right, biopsy: Negative for neoplasm.

With available surgical material [AJCC pT1bN2] (7th edition, 2010).

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

[page 3 of 4]
GROSS DESCRIPTION:

A. Received fresh labeled "ileal serosa" is a 0.6 x 0.1 x 0.1 cm fragment of pink-tan soft tissue. All submitted.

B. Received fresh labeled "anterior vaginal margin" is a 1.2 x 1.1 x 0.8 cm fragment of pink-tan tissue without orientation. All submitted.

C. Received fresh labeled "uterus right and left fallopian tubes and ovaries" is a 118.9 gram uterus with attached bilateral tubes and ovaries. The uterine serosa smooth. There is a 5.5 x 5.2 x 1.5 cm exophytic infiltrative mass in the right lateral site of the endometrial cavity grossly invading 2.0 cm. The myometrial thickness is 2.1 cm. There are no leiomyomata. There is a 2.5 x 1.9 x 1.4 cm right ovary with a smooth outer surface and a solid cut surface. Right fallopian tube is not identified. There is a 2.3 x 1.8 x 1.5 cm left ovary with a smooth outer surface and a solid cut surface. Left fallopian tube is not identified. Representative sections are submitted.

D. Received fresh labeled "left pelvic lymph nodes" is an 8.3 x 6.0 x 2.0 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

E. Received fresh labeled "right pelvic lymph nodes" is a 13.7 x

[page 4 of 4]
7.4 x 1.8 cm aggregate of adipose and lymphatic tissue.
Lymph nodes
submitted.

F. Received fresh labeled "omentum" is a 60.0 x 22.0 x
2.0 cm
portion of omentum. No masses are identified grossly.
Lymph nodes
are not identified. Representative sections are
submitted. Grossed
by

G. Received fresh labeled "left para-aortic lymph nodes
above IMA"
is a 2.5 x 2.4 x 0.7 cm aggregate of adipose and tissue.
Lymph
nodes submitted.

H. Received fresh labeled "left para-aortic lymph nodes
below IMA"
is a 4.5 x 2.8 x 1.0 cm aggregate of adipose and lymphatic
tissue.
Lymph nodes submitted.

I. Received fresh labeled "left gonadal vessel" is a 5.5
cm in
length by 0.5 cm in diameter portion of unremarkable blood
vessel.
Representative sections are submitted.

J. Received fresh labeled "right para-aortic lymph nodes
above IMA"
is a 5.5 x 5.0 x 0.8 cm aggregate of adipose and lymphatic
tissue.
Lymph nodes submitted.

K. Received fresh labeled "right para-aortic lymph nodes
below IMA"
is a 2.8 x 2.5 x 1.3 cm aggregate of adipose and lymphatic
tissue.
Lymph nodes submitted.

L. Received fresh labeled "right gonadal vessel" is a 4.0
cm in
length by 0.3 cm in diameter portion of blood vessel.
Representative sections are submitted.

Dual/Synchronous Primary, Noted		///

Source: NCI Genomic Data Commons file 68b68a3a-a778-42e2-b7b5-99b1b0269b3b (TCGA-D1-A1NX.C2A3FA63-63A1-4424-BD92-FAEC1C377C62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).